TCGA case TCGA-AK-3434 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17d053f2-8760-4f8e-9d25-64508e7f3857

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.5 years (26,490 days); Year of diagnosis: 2004; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
2. Recurrence of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 77.0 years (28,130 days); Days to diagnosis: 1,640 days (4.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,640 days (4.5 years); Treatment anatomic sites: Locoregional Site.

Follow-up (2 entries)
- Day 1,640 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,640 days (4.5 years).
- Days to follow up: 2,087 days (5.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Lactate Dehydrogenase: Normal.
- Leukocytes: Normal.
- Calcium: Normal.
- Platelets: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AK-3434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.4.
  Slide TCGA-AK-3434-01A-01-BS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-AK-3434-01A-02-BS2: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35.
- Sample TCGA-AK-3434-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AK-3434-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: No.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,087 days; disease-specific survival: no event (censored), 2,087 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,640 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AK-3434-01): tumor purity 0.47, ploidy 3.87, whole-genome doublings 1 (call status: legacy_call).
